Gene-level copy-number profile of tumor specimen TCGA-OR-A5LC-01A from TCGA case TCGA-OR-A5LC, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 71.4 years (26,084 days).
Specimen TCGA-OR-A5LC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.f716c644-db79-4cba-8d8b-f54e6af86e45.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2bdcaa90-ea56-4398-829e-2863c0bc15a0

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 27; copy number 2: 8,987; copy number 3: 4,373; copy number 4: 14,778; copy number 6: 31,499; copy number 9: 33; copy number 10: 15; copy number 13: 79; copy number 15: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LC-01A-11D-A29H-01): tumor purity 0.92, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,352,397–8,848,921, 6 genes (within-gene range 0–3): RERE, RERE-AS1, AL096855.1, AL096855.2, RPL7P11, RPL7P7.
- chr4:181,686,182–181,700,142, 1 gene: AC084741.1.
- chr9:21,967,752–22,128,103, 6 genes (within-gene range 0–2): CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr11:128,836,315–128,943,399, 5 genes: KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1.
- chr22:28,992,721–29,168,333, 6 genes (within-gene range 0–3): ZNRF3-IT1, ZNRF3-AS1, C22orf31, KREMEN1, AL021393.1, RNU6-810P.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 81 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,309,377, 48 genes, copy number 13: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457.
- chr5:28,213,359–28,287,807, 2 genes, copy number 15: AC093300.1, LINC02103.
- chr5:31,639,131–32,110,932, 1 gene, copy number 13 (within-gene range 6–13): PDZD2.
- chr5:31,820,564–33,298,066, 30 genes, copy number 13 (within-gene range 6–13): RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
